Gene-level copy-number profile of tumor specimen MP2PRT-PAULBG-TMP1-A from MP2PRT case MP2PRT-PAULBG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,193 days).
Specimen MP2PRT-PAULBG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2250e520-e550-429d-8a66-6d15d839b42c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAULBG-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/8e864156-4be0-4f63-a05d-7432e6068453

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 3,498; copy number 2: 55,234; copy number 3: 47.

Homozygous deletions (total copy number 0; autosomes only): 119 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,040,224–89,085,787, 4 genes (within-gene range 0–1): IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15.
- chr2:89,170,775–89,192,752, 4 genes (within-gene range 0–1): IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–1): TRDD1, TRDD2.
- chr14:105,851,705–106,174,760, 70 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,715,181, 36 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48, IGHV3-49, IGHVII-49-1, IGHV3-50, IGHV5-51, IGHV8-51-1, IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55, IGHV7-56, IGHV3-57, IGHV1-58, IGHV4-59, IGHV3-60, RNA5SP389, IGHVII-60-1, IGHV4-61, IGHV3-62, IGHVII-62-1, IGHV3-63, IGHV3-64, IGHV3-65, IGHVII-65-1, IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 642. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
